Somatic mutation profile of tumor specimen MMRF_1318_1_BM_CD138pos (aliquot MMRF_1318_1_BM_CD138pos_T1_KAS5U_L01926) from MMRF case MMRF_1318, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.4 years (31,200 days).
Specimen MMRF_1318_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92941389-fb0a-4996-b61a-97456e2a5960.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1318_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1318_2_PB_Whole_C1_KAS5U_L01936; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13e06519-0e9e-4955-a568-0418480d6433

The open-access MAF lists 131 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 35, Silent 16, Intron 14, 5'UTR 5, 3'Flank 3, Nonsense Mutation 3, Splice Site 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 108/285 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs778521666; called by muse, mutect2, varscan2
- AGAP2 | c.1507G>T p.E503* (on ENST00000547588 / NM_001122772.2; = p.E167* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as rs1555199170; called by muse, mutect2, varscan2
- ARHGAP29 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs547690695; called by muse, mutect2, varscan2
- ARHGEF15 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs587777166, CM136400, COSV62725476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN2 | c.1763G>A p.S588N (on ENST00000313400 / NM_001365069.1; = p.S537N on NM_014010.5) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV57799363; called by muse, mutect2, varscan2
- FAT3 | c.7730G>C p.G2577A | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV99961560; called by muse, mutect2, varscan2
- HTR1F | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60389395; called by muse, mutect2, varscan2
- IGHV2-70 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs370008108; called by muse, varscan2
- IGLV3-1 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs185803370; called by muse, varscan2
- LMTK3 | c.1959C>G p.D653E | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs1248628218; called by muse, mutect2, varscan2
- MRGPRF | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1267722077, COSV100307780; called by muse, mutect2, varscan2
- OCA2 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs549983090; called by muse, mutect2, varscan2
- PGAM2 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1129639; called by muse, mutect2, varscan2
- PHF20 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as COSV59186928; called by muse, mutect2, varscan2
- RIC8B | c.1361C>A p.A454D | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100822510; called by muse, mutect2, varscan2
- SLC25A36 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs375575933; called by muse, mutect2, varscan2
- SMAD3 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1348033858, COSV59284704; ClinVar: uncertain significance; called by muse, mutect2
- ST8SIA4 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 126/294 reads (43%) | catalogued as COSV51506800; called by muse, mutect2, varscan2
- STARD7 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1341083499; called by muse, mutect2
- THEG | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.36); catalogued as rs767462288, COSV61074227; called by muse, mutect2, varscan2
- TNNT2 | c.774C>A p.F258L (on ENST00000236918; = p.F255L on NM_000364.4) | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV52663865; called by muse, mutect2, varscan2
- VWA2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as rs367836452, COSV53911510; called by muse, varscan2
- ZNF648 | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100374840, COSV60571758; called by muse, mutect2, varscan2
- ANKRD13A | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ARHGAP10 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOC | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 79/108 reads (73%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1H | c.2939T>C p.L980P | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALCR | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDHR1 | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CGNL1 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CORO2A | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2
- GPR39 | c.86T>A p.I29N | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GTF3C4 | c.2316-5_2316-2del p.X772_splice | Splice Site (DEL) | VAF 86/266 reads (32%) | called by mutect2, varscan2
- HCFC1 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, varscan2
- HTRA1 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ICE2 | c.1246T>A p.S416T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKC | c.90T>G p.N30K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1328 | c.1184T>G p.L395R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KPNA6 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LINGO2 | c.1639A>G p.M547V | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LPL | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MDN1 | c.13904C>T p.T4635I | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MTRR | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5AC | c.13580C>G p.T4527S | Missense Mutation (SNP) | VAF 132/371 reads (36%) | SIFT tolerated (1); called by muse, varscan2
- NAALADL2 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OSMR | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- PRRC2A | c.5192G>C p.G1731A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PTPRQ | c.4612T>G p.L1538V (on ENST00000616559; = p.L1496V on NM_001145026.2) | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEMA3E | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A1 | c.1159T>C p.S387P | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLITRK6 | c.1671G>C p.L557F | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRIM23 | c.1180-1G>C p.X394_splice | Splice Site (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- WNK2 | c.4878A>T p.R1626S (on ENST00000297954 / NM_001282394.1; = p.R1589S on NM_006648.3) | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF562 | c.388T>A p.C130S (on ENST00000453372 / NM_001130032.2; = p.C58S on NM_017656.4) | Missense Mutation (SNP) | VAF 320/981 reads (33%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF687 | c.3340T>C p.Y1114H | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADH7 | c.1155G>A p.T385= | Silent (SNP) | VAF 216/503 reads (43%) | catalogued as rs748999489, COSV52920157; called by muse, mutect2, varscan2
- DOCK5 | c.4563C>T p.T1521= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as rs753572778; called by muse, mutect2, varscan2
- ESR1 | c.1008C>G p.P336= | Silent (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- GALT | c.1077G>A p.R359= | Silent (SNP) | VAF 83/281 reads (30%) | catalogued as rs148967210; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs367953381; called by muse, varscan2
- LCK | c.153C>T p.Y51= | Silent (SNP) | VAF 60/103 reads (58%) | catalogued as rs950834998, COSV100287352; called by muse, mutect2, varscan2
- MTCL1 | c.5166C>T p.A1722= (on ENST00000306329 / NM_001378206.1; = p.A1403= on NM_015210.4) | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs367711662; called by muse, mutect2, varscan2
- OR10S1 | c.45G>A p.E15= | Silent (SNP) | VAF 148/410 reads (36%) | catalogued as COSV73342769; called by muse, mutect2, varscan2
- PGR | c.2781C>T p.P927= | Silent (SNP) | VAF 94/108 reads (87%) | called by muse, mutect2, varscan2
- PI4KA | c.2925C>T p.F975= | Silent (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- POU4F3 | c.621C>T p.D207= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as COSV57943330; called by muse, mutect2, varscan2
- PTPRS | c.1167C>T p.I389= | Silent (SNP) | VAF 77/113 reads (68%) | catalogued as rs1288395296; called by muse, mutect2, varscan2
- STK35 | c.486G>T p.T162= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- TRPC5 | c.1734T>G p.S578= | Silent (SNP) | VAF 96/97 reads (99%) | called by muse, mutect2, varscan2
- TTN | c.39927C>T p.D13309= (on ENST00000591111; = p.D5885= on NM_003319.4) | Silent (SNP) | VAF 84/180 reads (47%) | catalogued as rs371376631; called by muse, mutect2, varscan2
- USH2A | c.3801G>A p.A1267= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs537863698, COSV100231306, COSV56451059; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AC048334.1 | n.139C>T | RNA (SNP) | VAF 94/151 reads (62%) | called by muse, mutect2, varscan2
- AC098650.1 | c.*115+16119A>G | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs1335944798; called by muse, mutect2, varscan2
- ATG7 | c.*2307T>A | 3'UTR (SNP) | VAF 88/125 reads (70%) | called by muse, mutect2, varscan2
- BTBD3 | c.-219G>C | 5'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- CACNG8 | c.*322del | 3'UTR (DEL) | VAF 24/49 reads (49%) | called by mutect2, pindel, varscan2
- CD46 | c.*393A>G | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- CHCHD1 | c.244-308A>T | Intron (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- COBL | c.1096+20436T>C | Intron (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- COL3A1 | c.*317C>A | 3'UTR (SNP) | VAF 76/146 reads (52%) | catalogued as rs886055337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMMD2 | c.*2929G>C | 3'UTR (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- CXCR5 | c.51+2259C>G | Intron (SNP) | VAF 110/225 reads (49%) | called by muse, mutect2, varscan2
- DCAF11 | c.*409C>T | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- DIP2B | c.*2814C>T | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- EXOC3L1 | c.-7-101C>T | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, varscan2
- FAM120A | c.1734+887T>C | Intron (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- FAM89B | c.*283G>A | 3'UTR (SNP) | VAF 68/191 reads (36%) | called by muse, mutect2, varscan2
- GABRG2 | c.1042+31T>C | Intron (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100729808; called by muse, mutect2, varscan2
- GGPS1 | c.*1425C>A | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- GIGYF1 | c.*1019G>T | 3'UTR (SNP) | VAF 90/166 reads (54%) | called by muse, mutect2, varscan2
- GPR89B | c.-60C>G | 5'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as rs1229801308; called by muse, mutect2
- H6PD | c.*4178_*4179insG | 3'UTR (INS) | VAF 31/99 reads (31%) | called by mutect2, varscan2
- HDAC5 | c.2051-89G>C | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- HP1BP3 | c.*278A>G | 3'UTR (SNP) | VAF 33/81 reads (41%) | catalogued as rs1162949308; called by muse, mutect2, varscan2
- JCAD | c.*2182T>C | 3'UTR (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- LCE1A | c.*179C>T | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- LIMD1 | chr3:45689086 C>T | 3'Flank (SNP) | VAF 30/54 reads (56%) | catalogued as rs569459523; called by muse, mutect2, varscan2
- MAPRE2 | c.*2987A>G | 3'UTR (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- MIOS | c.2402-18C>T | Intron (SNP) | VAF 71/134 reads (53%) | catalogued as rs927943372; called by muse, mutect2, varscan2
- MTG1 | c.*646G>A | 3'UTR (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- NEDD1 | c.*192C>T | 3'UTR (SNP) | VAF 87/160 reads (54%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3469C>G | Intron (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- OLFM3 | c.*241_*242insG | 3'UTR (INS) | VAF 14/78 reads (18%) | catalogued as rs1268048037; called by mutect2, pindel, varscan2
- OVOL1 | c.-15G>A | 5'UTR (SNP) | VAF 48/139 reads (35%) | catalogued as rs1026079794; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11833T>C | Intron (SNP) | VAF 90/188 reads (48%) | called by muse, mutect2, varscan2
- PLEKHB2 | chr2:131149048 T>A | 3'Flank (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- PPP1R15B | c.*321T>C | 3'UTR (SNP) | VAF 46/81 reads (57%) | called by muse, mutect2, varscan2
- PROCR | c.*34G>C | 3'UTR (SNP) | VAF 42/84 reads (50%) | catalogued as COSV99405773; called by muse, mutect2, varscan2
- PRR19 | c.-6-87del | Intron (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.-34G>A | 5'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- QSER1 | c.*3088T>C | 3'UTR (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- RAB22A | c.*7413C>T | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.*964T>C | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- SLC2A13 | c.*1731T>C | 3'UTR (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- SP3 | c.*997T>G | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SP5 | chr2:170712451 C>T | 5'Flank (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- SPSB4 | c.*1125_*1145del | 3'UTR (DEL) | VAF 86/142 reads (61%) | called by mutect2, pindel, varscan2
- SRRM4 | c.*3769C>A | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*4249T>A | 3'UTR (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
- TAF5 | c.*594A>C | 3'UTR (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- TMEM154 | c.*3336G>A | 3'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs1485061768; called by muse, mutect2, varscan2
- TRIM7 | c.619-193A>G | Intron (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- TSSK1B | c.*893T>C | 3'UTR (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- VCL | c.*1825G>A | 3'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- VPS13C | c.-21T>G | 5'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- WIPF2 | c.*5398G>A | 3'UTR (SNP) | VAF 52/95 reads (55%) | called by muse, mutect2, varscan2
- ZNF568 | c.*523T>A | 3'UTR (SNP) | VAF 76/279 reads (27%) | called by muse, mutect2, varscan2
- ZNF676 | chr19:22179863 C>T | 3'Flank (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- ZNRD2 | c.20-21C>A | Intron (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.*292C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
